Somatic mutation profile of tumor specimen MMRF_1680_1_BM_CD138pos (aliquot MMRF_1680_1_BM_CD138pos_T1_KBS5U_K11932) from MMRF case MMRF_1680, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.5 years (20,275 days).
Specimen MMRF_1680_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ea718e8-d209-49f4-a665-3d083f73a9d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1680_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1680_1_PB_CD3pos_C2_KBS5U_K11926; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35e489e0-f151-42dc-acb0-9eaadb3df3f6

The open-access MAF lists 127 somatic variants for this specimen: 51 protein-altering or splice-affecting, 17 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 34, Silent 17, Intron 7, 3'Flank 6, Splice Site 6, 5'Flank 6, 5'UTR 5, Frame Shift Del 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374172791, CM014320; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.23020-1G>A p.X7674_splice (on ENST00000367255 / NM_182961.4; = p.X7603_splice on NM_033071.3) | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as rs1554544827; ClinVar: pathogenic; called by muse, varscan2
- AKT1 | c.176-2A>G p.X59_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV62572975; called by muse, mutect2, varscan2
- C9 | c.1111+1G>T p.X371_splice | Splice Site (SNP) | VAF 44/84 reads (52%) | catalogued as rs544567518, COSV54680280; called by muse, mutect2, varscan2
- CCS | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV100040245; called by muse, mutect2
- CD2 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV65643486; called by muse, mutect2, varscan2
- CELF5 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV53014086; called by muse, mutect2, varscan2
- EPB41L5 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 7/184 reads (4%) | catalogued as COSV55355001; called by muse, mutect2
- FAM180A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs890848627, COSV100647213; called by muse, mutect2, varscan2
- FLRT2 | c.766A>T p.R256W | Missense Mutation (SNP) | VAF 106/112 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV58149044, COSV58152878; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.608); catalogued as rs963887726; called by muse, mutect2
- IGHV2-70 | c.47-2A>T p.X16_splice | Splice Site (SNP) | VAF 43/99 reads (43%) | catalogued as rs753431003; called by muse, varscan2
- IGKJ5 | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 36/44 reads (82%) | catalogued as rs142632901; called by muse, varscan2
- KBTBD13 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs1291529388, COSV101416686; called by muse, mutect2, varscan2
- PCDH18 | c.2716C>T p.L906F | Missense Mutation (SNP) | VAF 137/266 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV61272775; called by muse, mutect2, varscan2
- PCSK1 | c.1622G>C p.R541P | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV60736405; called by muse, mutect2, varscan2
- PHEX | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV65080276; called by muse, mutect2
- RASGRP3 | c.1739C>G p.T580S (on ENST00000402538 / NM_001349975.2; = p.T579S on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101274906; called by muse, mutect2, varscan2
- RNF111 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs866475602; called by muse, mutect2, varscan2
- SLF2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1301205064, COSV53276869; called by muse, mutect2
- VASP | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs752897849; called by muse, mutect2, varscan2
- ZFYVE26 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61332893; called by muse, mutect2, varscan2
- AASDH | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ACSL5 | c.124C>T p.L42F (on ENST00000354273; = p.L98F on NM_016234.3) | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPD3 | c.796A>T p.T266S (on ENST00000396553 / NM_001025389.2; = p.T275S on NM_000480.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ATP13A5 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2
- ATP13A5 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK9 | c.154A>G p.M52V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- ENPP2 | c.388_389insA p.C130* | Nonsense Mutation (INS) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- EXT2 | c.744-1G>A p.X248_splice (on ENST00000343631; = p.X281_splice on NM_000401.3) | Splice Site (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- FAM78A | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GOLGB1 | c.6536A>C p.N2179T | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- IGHV2-70 | c.47-1G>C p.X16_splice | Splice Site (SNP) | VAF 43/100 reads (43%) | called by muse, varscan2
- IGHV2-70D | c.206T>A p.L69H | Missense Mutation (SNP) | VAF 62/66 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KBTBD11 | c.583C>G p.R195G | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- LMTK2 | c.3876C>G p.D1292E | Missense Mutation (SNP) | VAF 138/261 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MRPL1 | c.833T>G p.V278G | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- MYO10 | c.833T>G p.F278C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- OR2G3 | c.747del p.I250Yfs*6 | Frame Shift Del (DEL) | VAF 76/269 reads (28%) | called by mutect2, varscan2
- OR4F6 | c.628T>A p.S210T | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PNCK | c.694G>T p.D232Y (on ENST00000340888 / NM_001366975.1; = p.D315Y on NM_001039582.3) | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PTPRU | c.3175C>T p.H1059Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PXDN | c.2941C>A p.Q981K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SEC16A | c.3568G>T p.D1190Y | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SIX2 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- UBTD1 | c.639del p.F213Lfs*135 | Frame Shift Del (DEL) | VAF 45/115 reads (39%) | called by mutect2, pindel, varscan2
- UHRF1BP1 | c.2409C>A p.N803K | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZAN | c.3579C>A p.F1193L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZDBF2 | c.4973G>A p.C1658Y | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF484 | c.1862C>T p.S621L | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF652 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCA1 | c.5523G>A p.V1841= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- ALOXE3 | c.1383C>T p.L461= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- BSND | c.186C>T p.F62= | Silent (SNP) | VAF 18/302 reads (6%) | catalogued as rs751062690, COSV64870489; called by muse, mutect2
- DGKG | c.576C>T p.N192= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs768853121, COSV53966125; called by muse, mutect2, varscan2
- DOCK2 | c.1278C>T p.I426= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, varscan2
- FAM189A1 | c.339C>T p.L113= | Silent (SNP) | VAF 84/547 reads (15%) | catalogued as rs1026329369; called by muse, mutect2, varscan2
- GATAD1 | c.429C>T p.F143= | Silent (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- KIF7 | c.4026C>T p.P1342= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.1164T>A p.S388= | Silent (SNP) | VAF 103/219 reads (47%) | called by muse, mutect2, varscan2
- MTF2 | c.1635C>G p.L545= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV64771922; called by muse, mutect2, varscan2
- NLRC3 | c.477C>T p.V159= | Silent (SNP) | VAF 53/95 reads (56%) | called by muse, mutect2, varscan2
- PES1 | c.1560T>C p.D520= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs751094429; called by muse, mutect2, varscan2
- PRRT3 | c.2937C>T p.I979= | Silent (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- RXRB | c.129G>A p.L43= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1260700684; called by muse, mutect2, varscan2
- TRIM33 | c.414G>A p.A138= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- WDFY3 | c.256C>A p.R86= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as COSV99883043; called by muse, mutect2, varscan2
- ZBTB7B | c.1317C>T p.F439= (on ENST00000292176; = p.F473= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as rs746864508, COSV52691456; called by muse, mutect2
- ABLIM1 | chr10:114432492 T>G | 3'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- ATP10A | c.*1388C>T | 3'UTR (SNP) | VAF 63/115 reads (55%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*2731C>T | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- BET1 | c.-131C>G | 5'UTR (SNP) | VAF 87/165 reads (53%) | catalogued as COSV99747468; called by muse, mutect2, varscan2
- BRWD1 | c.*514C>T | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- C11orf68 | chr11:65916820 C>T | 3'Flank (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- C4orf46 | c.*1536A>C | 3'UTR (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- C6orf136 | c.72+502C>T | Intron (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949030 C>T | 3'Flank (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- CADM2 | chr3:86067265 T>C | 3'Flank (SNP) | VAF 38/98 reads (39%) | called by muse, mutect2, varscan2
- CD226 | c.*3243C>A | 3'UTR (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- CETN3 | chr5:90410178 T>A | 5'Flank (SNP) | VAF 62/138 reads (45%) | called by muse, mutect2, varscan2
- CLYBL | c.928-6259T>C | Intron (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- CRYBG3 | c.*1127dup | 3'UTR (INS) | VAF 63/151 reads (42%) | called by mutect2, pindel, varscan2
- CSMD2 | c.6862+921C>T | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- CST9 | c.*176C>T | 3'UTR (SNP) | VAF 8/58 reads (14%) | catalogued as rs1243637415; called by muse, mutect2, varscan2
- DDAH1 | c.*1935G>C | 3'UTR (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- EFHC1 | c.1852-6096C>G | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- FAM149B1 | c.*1333C>T | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- FGF10 | c.*347A>G | 3'UTR (SNP) | VAF 69/152 reads (45%) | called by muse, mutect2, varscan2
- FRMD3 | c.*3149T>A | 3'UTR (SNP) | VAF 23/209 reads (11%) | called by muse, mutect2
- FUT7 | chr9:137034916 G>A | 5'Flank (SNP) | VAF 82/159 reads (52%) | catalogued as rs371583136; called by muse, mutect2, varscan2
- H4C2 | c.*12G>C | 3'UTR (SNP) | VAF 108/244 reads (44%) | called by muse, varscan2
- IGHV5-51 | c.-25G>A | 5'UTR (SNP) | VAF 57/122 reads (47%) | catalogued as rs781786590; called by muse, mutect2, varscan2
- LCK | c.*235G>A | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- LDHA | c.*429C>T | 3'UTR (SNP) | VAF 22/188 reads (12%) | catalogued as rs549767576; called by muse, mutect2, varscan2
- LMLN | c.*2734T>G | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851184 A>T | 5'Flank (SNP) | VAF 121/218 reads (56%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851318 G>A | 5'Flank (SNP) | VAF 80/163 reads (49%) | catalogued as rs184165450; called by muse, mutect2, varscan2
- MTF2 | c.*61C>T | 3'UTR (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100940101; called by muse, mutect2, varscan2
- MYO1E | c.-63C>T | 5'UTR (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- NGFR | c.*519G>C | 3'UTR (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- NPR3 | c.*535C>T | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- NTRK3 | c.2133+12778T>A | Intron (SNP) | VAF 69/123 reads (56%) | called by muse, mutect2, varscan2
- OR5E1P | n.845T>C | RNA (SNP) | VAF 88/225 reads (39%) | called by muse, mutect2, varscan2
- OTUD6B | c.*2066T>C | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- PLOD2 | c.*793dup | 3'UTR (INS) | VAF 53/152 reads (35%) | catalogued as rs562534224; called by mutect2, varscan2
- PLPBP | c.*1151G>A | 3'UTR (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- POU2F1 | c.-116G>A | 5'UTR (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- PPP1R1A | c.*758A>T | 3'UTR (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- PRRG4 | c.*1198G>A | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- RAB3B | c.*2107G>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- RAD23B | c.*336T>G | 3'UTR (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- RGPD1 | c.*974G>C | 3'UTR (SNP) | VAF 51/413 reads (12%) | called by muse, mutect2, varscan2
- RIMS1 | chr6:72401204 C>T | 3'Flank (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- RNF168 | c.*2367G>A | 3'UTR (SNP) | VAF 5/110 reads (5%) | catalogued as rs895362848; called by muse, mutect2
- SENP6 | chr6:75601541 A>C | 5'Flank (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- SLC26A2 | c.*4140A>G | 3'UTR (SNP) | VAF 53/116 reads (46%) | called by muse, mutect2, varscan2
- SMYD3 | c.532-266A>G | Intron (SNP) | VAF 10/266 reads (4%) | called by muse, mutect2
- SP100 | c.*923G>A | 3'UTR (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- STK4 | c.*2101G>A | 3'UTR (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- SUFU | c.1296+452C>T | Intron (SNP) | VAF 34/190 reads (18%) | called by muse, mutect2, varscan2
- SUV39H1 | c.*1445A>G | 3'UTR (SNP) | VAF 32/32 reads (100%) | called by muse, mutect2, varscan2
- TACR3 | c.*1397T>C | 3'UTR (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- TEX15 | chr8:30849153 A>C | 5'Flank (SNP) | VAF 139/279 reads (50%) | called by muse, mutect2, varscan2
- TM7SF2 | c.-136_-120del | 5'UTR (DEL) | VAF 37/103 reads (36%) | called by mutect2, varscan2
- TRPS1 | chr8:115410601 C>T | 3'Flank (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- VPS13D | c.*2420G>A | 3'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- ZNF568 | c.*171A>C | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
